BEATAML1.0 case 2664 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/df42b0e1-55b8-463b-97bb-e3b9f85ac3e8

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Mixed phenotype acute leukemia, T/myeloid, NOS: ICD-O-3 morphology code: 9809/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.0 years (18,252 days); Progression or recurrence: no.

Biospecimens (3 samples)
- Sample BA3153D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA3153R: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
- Sample BA3391D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
